Somatic mutation profile of tumor specimen C3L-00094-03 (aliquot CPT0000920005) from CPTAC case C3L-00094, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 70.0 years (25,560 days).
Specimen C3L-00094-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ced282a1-fe60-4601-9124-493f97fddd84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00094-31 (Blood Derived Normal), aliquot CPT0003900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5878cdf6-e9ce-41de-bfd2-7dff7b415887

The open-access MAF lists 281 somatic variants for this specimen: 196 protein-altering or splice-affecting, 50 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 50, Intron 22, Nonsense Mutation 17, Frame Shift Del 8, 3'UTR 5, Splice Site 5, 5'Flank 3, 5'UTR 3, Frame Shift Ins 3, RNA 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 103/313 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.15052+1G>A p.X5018_splice | Splice Site (SNP) | VAF 16/424 reads (4%) | catalogued as rs1553249290; ClinVar: likely pathogenic; called by muse, mutect2
- ADAM2 | c.345-1G>T p.X115_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99052372; called by muse, varscan2
- ANKIB1 | c.2225G>C p.R742T | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99728055; called by muse, mutect2, varscan2
- AVPR1A | c.353G>C p.R118P | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as COSV54547129; called by muse, mutect2, varscan2
- C7 | c.2114G>T p.W705L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100496453; called by muse, mutect2, varscan2
- CCDC168 | c.15302C>G p.S5101C | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs1043517842; called by muse, mutect2
- CDH7 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs867768827, COSV59881646, COSV59895818; called by muse, mutect2, varscan2
- CEACAM18 | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 158/512 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67284351; called by muse, mutect2, varscan2
- CELSR2 | c.4832A>C p.Q1611P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1022325245; called by muse, mutect2
- CTNNA3 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV65585521; called by muse, varscan2
- DNAH8 | c.10100G>C p.W3367S | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59435064; called by muse, mutect2, varscan2
- DSP | c.3905G>T p.R1302L | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.373); catalogued as rs760691999, COSV65793829; called by muse, mutect2, varscan2
- E2F3 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1347621462; called by muse, varscan2
- ENG | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs756016748; called by muse, mutect2, varscan2
- FLT1 | c.712C>A p.R238S | Missense Mutation (SNP) | VAF 116/394 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV56726157; called by muse, mutect2, varscan2
- GDPD2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV65533335; called by muse, varscan2
- GMIP | c.1086del p.A363Pfs*11 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as COSV52558512; called by mutect2, pindel, varscan2
- GRIN2B | c.21C>A p.C7* | Nonsense Mutation (SNP) | VAF 20/232 reads (9%) | catalogued as rs751673148; called by muse, mutect2
- H2AC13 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs1352467959, COSV62440432; called by muse, mutect2
- INKA1 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs1386143976; called by muse, mutect2, varscan2
- ITGA1 | c.1701C>A p.C567* | Nonsense Mutation (SNP) | VAF 27/258 reads (10%) | catalogued as COSV50877236; called by muse, mutect2, varscan2
- ITIH4 | c.2191G>T p.A731S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.09); catalogued as COSV56577907; called by muse, varscan2
- KRT27 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 42/147 reads (29%) | catalogued as rs748955660, COSV100053197; called by muse, mutect2, varscan2
- MANEA | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV62589311; called by muse, varscan2
- MCHR2 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 62/451 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs1362241895; called by muse, mutect2, varscan2
- MCM6 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1244751118; called by muse, mutect2
- MINAR1 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100548993; called by muse, mutect2, varscan2
- MOG | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.676); catalogued as COSV65306292; called by muse, mutect2, varscan2
- MUC4 | c.5891G>T p.G1964V | Missense Mutation (SNP) | VAF 108/503 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.955); catalogued as rs763003212; called by muse, varscan2
- MYOC | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV104377617; called by muse, mutect2
- NCR1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772041783, COSV52557607; called by muse, mutect2, varscan2
- NIBAN2 | c.2200A>G p.T734A | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.037); catalogued as rs1268942506; called by muse, mutect2, varscan2
- OR14C36 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100507682; called by muse, mutect2, varscan2
- OR2T6 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63217048; called by muse, mutect2, varscan2
- OR4M1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100270954, COSV60061572; called by muse, mutect2
- OR9G1 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs769555188, COSV99044031; called by muse, mutect2, varscan2
- PABPC4L | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756917832, COSV69929728; called by muse, mutect2
- PARP8 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV55866776; called by muse, mutect2, varscan2
- PCDHGA5 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs761134623; called by muse, mutect2, varscan2
- PHF3 | c.3433C>T p.R1145C | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746692332; called by muse, mutect2, varscan2
- PRKDC | c.10274G>T p.R3425L | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377205091; called by muse, mutect2, varscan2
- RALGPS2 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs561069653, COSV100243679; called by muse, mutect2, varscan2
- RBP3 | c.3622G>A p.G1208R | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206764279; ClinVar: uncertain significance; called by muse, mutect2
- RFX6 | c.1869C>A p.D623E | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs137956032; called by muse, varscan2
- RSRC2 | c.1094A>T p.N365I | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV59206438; called by muse, mutect2
- SAMSN1 | c.771G>T p.W257C (on ENST00000647101; = p.W29C on NM_001256370.1) | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.641); catalogued as rs200030823; called by muse, mutect2, varscan2
- SLC17A8 | c.1363G>T p.G455* | Nonsense Mutation (SNP) | VAF 173/590 reads (29%) | catalogued as rs1474758888; called by muse, mutect2, varscan2
- SLC25A40 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs1188851853; called by muse, mutect2, varscan2
- SNAPC3 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs967616976; called by muse, mutect2, varscan2
- STXBP6 | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 205/316 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV60589867; called by muse, mutect2, varscan2
- TBC1D4 | c.2702G>T p.R901I | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66488609; called by muse, mutect2, varscan2
- THBS2 | c.3082G>A p.V1028I | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.457); catalogued as rs769462618; called by muse, mutect2
- TRPA1 | c.1815G>T p.W605C | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV100084273, COSV51557504; called by muse, mutect2, varscan2
- TRPM7 | c.1495-1G>A p.X499_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100539720; called by muse, mutect2, varscan2
- TSG101 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV52651459; called by muse, mutect2, varscan2
- TSHZ3 | c.1544G>T p.S515I | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99078531; called by muse, varscan2
- TTK | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as rs763183104; called by muse, mutect2, varscan2
- UACA | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs139165884; called by muse, mutect2, varscan2
- UNC79 | c.4745G>C p.R1582T (on ENST00000393151 / NM_001346218.2; = p.R1405T on NM_020818.5) | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV99829956; called by muse, mutect2, varscan2
- VPS39 | c.1594C>A p.P532T (on ENST00000348544 / NM_001301138.2; = p.P521T on NM_015289.5) | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV58789902; called by muse, mutect2, varscan2
- ZIC4 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV67172967; called by muse, mutect2, varscan2
- ZIM3 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54142495; called by muse, mutect2, varscan2
- ZNF547 | c.74G>T p.W25L | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750936805; called by muse, mutect2
- ABCG1 | c.1742G>T p.G581V | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACBD5 | c.712G>T p.G238C (on ENST00000375888 / NM_001352568.1; = p.G229C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/321 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ADAD1 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAD1 | c.259A>T p.I87L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.346); called by muse, mutect2
- AFAP1 | c.2071G>T p.G691C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK2 | c.11359G>T p.G3787W | Missense Mutation (SNP) | VAF 155/465 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- AKAP6 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 431/562 reads (77%) | SIFT tolerated (0.18); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- AMOTL1 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANAPC7 | c.809A>T p.N270I | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANHX | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ARHGAP25 | c.254A>G p.K85R (on ENST00000409202 / NM_001007231.3; = p.K78R on NM_014882.3) | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.609); called by muse, mutect2
- ARHGAP39 | c.3182G>T p.R1061L (on ENST00000276826 / NM_001308208.2; = p.R1092L on NM_025251.2) | Missense Mutation (SNP) | VAF 117/195 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARMC3 | c.1594T>C p.S532P | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BBS7 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, varscan2
- BNC2 | c.1601del p.P534Lfs*13 | Frame Shift Del (DEL) | VAF 40/291 reads (14%) | called by mutect2, pindel, varscan2
- C10orf62 | c.530A>T p.K177M | Missense Mutation (SNP) | VAF 108/304 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C4orf54 | c.4249C>T p.Q1417* | Nonsense Mutation (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- CAST | c.886G>T p.A296S (on ENST00000341926; = p.A379S on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CCDC185 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC28A | c.227A>G p.H76R | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDHR5 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHL1 | c.3428C>A p.P1143H (on ENST00000397491 / NM_001253387.1; = p.P1159H on NM_006614.4) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHRND | c.1154C>A p.S385Y | Missense Mutation (SNP) | VAF 97/514 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CLEC18B | c.584T>A p.I195N | Missense Mutation (SNP) | VAF 166/1388 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CNGA3 | c.1615G>T p.V539L | Missense Mutation (SNP) | VAF 214/503 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CNGA4 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- COL9A3 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 124/465 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORO6 | c.1365G>T p.Q455H | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRYBA4 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.332); called by muse, varscan2
- CTNNA2 | c.2190A>T p.R730S | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCDC1 | c.237del p.N80Tfs*35 | Frame Shift Del (DEL) | VAF 42/284 reads (15%) | called by mutect2, pindel*, varscan2
- DCT | c.948C>G p.S316R | Missense Mutation (SNP) | VAF 67/298 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIDO1 | c.2613dup p.Q872Tfs*8 | Frame Shift Ins (INS) | VAF 18/157 reads (11%) | called by mutect2, pindel
- DMD | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 106/217 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by mutect2, varscan2
- DMXL2 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- DYSF | c.1492G>T p.G498C | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- EBLN1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.208); called by muse, mutect2
- EYS | c.2305G>T p.E769* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- FAT3 | c.1208A>C p.E403A | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FBN2 | c.4430A>T p.E1477V | Missense Mutation (SNP) | VAF 123/396 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- FHOD3 | c.2525_2526insG p.P844Tfs*17 (on ENST00000359247 / NM_001281739.3; = p.P861Tfs*17 on NM_025135.5) | Frame Shift Ins (INS) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- FYN | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FZD10 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GCA | c.460A>T p.R154W | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GCNT1 | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRID2IP | c.2755C>T p.Q919* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- H2AC1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2AC1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- HABP4 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- HAS2 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAVCR2 | c.466G>T p.G156* | Nonsense Mutation (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2
- HAVCR2 | c.465G>T p.R155S | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- HSF2BP | c.698T>A p.M233K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- HSP90AB1 | c.44T>C p.F15S | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPB6 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HTR1E | c.728G>C p.C243S | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IGLON5 | c.622C>A p.R208S | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- JAKMIP1 | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- JAZF1 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- KCNH8 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- KCTD11 | c.122T>C p.L41P (on ENST00000333751 / NM_001363642.1; = p.L2P on NM_001002914.2) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KIAA2012 | c.1177C>G p.P393A | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.8146T>C p.C2716R | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC3C | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP26 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP2 | c.1214_1216delinsTT p.T405Ifs*73 (on ENST00000461854 / NM_001278372.2; = p.T381Ifs*73 on NM_005374.5) | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by pindel, varscan2*
- MPP4 | c.956A>T p.Q319L | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MPRIP | c.*30G>T | Splice Region (SNP) | VAF 68/259 reads (26%) | called by muse, mutect2, varscan2
- MRAP | c.107-5del | Splice Region (DEL) | VAF 69/386 reads (18%) | called by mutect2, pindel, varscan2
- MRRF | c.255G>T p.L85F | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2
- MYO16 | c.4421A>T p.D1474V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- MYO18B | c.1933T>C p.W645R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- NBEA | c.5713G>T p.D1905Y | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBN | c.2179del p.M727Wfs*24 | Frame Shift Del (DEL) | VAF 161/429 reads (38%) | called by mutect2, pindel, varscan2
- NCOA6 | c.6001A>G p.S2001G | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); called by muse, varscan2
- NEURL4 | c.3458G>T p.R1153L | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NKX2-5 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPAP1 | c.660C>A p.S220R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NRG1 | c.809A>T p.Q270L (on ENST00000405005 / NM_013964.5; = p.Q275L on NM_013956.5) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NT5C1B | c.1229C>A p.T410N (on ENST00000359846 / NM_001199086.2; = p.T350N on NM_033253.4) | Missense Mutation (SNP) | VAF 157/436 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP98 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 36/111 reads (32%) | called by muse, mutect2, varscan2
- ONECUT3 | c.1340T>C p.I447T | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4K15 | c.80A>T p.E27V (on ENST00000305051; = p.E3V on NM_001005486.1) | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR52E2 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR5D13 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- P2RY8 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 154/411 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PBLD | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 69/176 reads (39%) | called by muse, mutect2, varscan2
- PCNX4 | c.1732G>A p.V578I (on ENST00000406854 / NM_001330177.2; = p.V344I on NM_022495.5) | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDCL | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 30/184 reads (16%) | called by muse, mutect2, varscan2
- PEX12 | c.79_83del p.D27Ffs*32 | Frame Shift Del (DEL) | VAF 174/630 reads (28%) | called by mutect2, pindel, varscan2
- PIGX | c.319-1G>T p.X107_splice | Splice Site (SNP) | VAF 11/64 reads (17%) | called by muse, varscan2
- PKHD1 | c.8951-1G>A p.X2984_splice | Splice Site (SNP) | VAF 48/177 reads (27%) | called by muse, mutect2, varscan2
- PPFIA2 | c.3635T>A p.M1212K | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PPP1R15B | c.62G>T p.W21L | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PREX1 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PTN | c.395A>T p.Q132L | Missense Mutation (SNP) | VAF 126/345 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PTPRD | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PXN | c.1700A>C p.Q567P (on ENST00000228307 / NM_001080855.3; = p.Q533P on NM_002859.4) | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- RNF213 | c.15590C>T p.A5197V | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RYR1 | c.9680G>T p.R3227L | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RYR2 | c.14302G>T p.V4768L | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SEMG2 | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- SETBP1 | c.4112C>T p.T1371I | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO1B3 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SPAM1 | c.1398T>A p.D466E | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPINT1 | c.464A>T p.Q155L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SPPL2A | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.823); called by muse, varscan2
- SPTBN4 | c.4339A>T p.S1447C | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SRCAP | c.8089G>T p.E2697* | Nonsense Mutation (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- SSTR3 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.047); called by muse, mutect2
- STK11 | c.152_153dup p.G52Wfs*13 | Frame Shift Ins (INS) | VAF 127/346 reads (37%) | called by mutect2, pindel, varscan2
- STON2 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 72/244 reads (30%) | called by muse, mutect2, varscan2
- SUPT6H | c.3425G>C p.R1142P | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SURF1 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D9 | c.544A>T p.S182C | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- TPCN2 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2
- TRIM58 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 23/301 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- TRPC1 | c.1468G>A p.D490N (on ENST00000476941 / NM_001251845.2; = p.D456N on NM_003304.4) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- TSSK1B | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBA1 | c.2847C>G p.N949K | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- UBQLN3 | c.1883T>C p.F628S | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNC13B | c.1049A>G p.K350R | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.10313C>A p.A3438E | Missense Mutation (SNP) | VAF 36/554 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- WNK2 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XKR7 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZEB1 | c.1269T>A p.N423K | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZEB2 | c.3014del p.D1005Afs*70 | Frame Shift Del (DEL) | VAF 177/551 reads (32%) | called by mutect2, pindel, varscan2
- ZNF479 | c.931_952del p.T311Ffs*52 | Frame Shift Del (DEL) | VAF 25/196 reads (13%) | called by mutect2, pindel, varscan2
- ZNF541 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 164/509 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ZNF677 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZNF800 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- ZNF831 | c.3262A>T p.R1088W | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- AAK1 | c.2583G>T p.G861= | Silent (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- ADPRS | c.228A>T p.T76= | Silent (SNP) | VAF 41/190 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1470G>T p.R490= | Silent (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- BCAS1 | c.1557C>T p.A519= | Silent (SNP) | VAF 163/639 reads (26%) | called by muse, mutect2, varscan2
- C1orf94 | c.1092C>A p.A364= (on ENST00000488417 / NM_001134734.2; = p.A174= on NM_032884.5) | Silent (SNP) | VAF 77/323 reads (24%) | called by muse, mutect2, varscan2
- CLTCL1 | c.660A>T p.V220= | Silent (SNP) | VAF 40/184 reads (22%) | called by muse, mutect2, varscan2
- DGKZ | c.1617G>T p.A539= (on ENST00000454345 / NM_001105540.2; = p.A351= on NM_003646.4) | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV58985828; called by muse, mutect2, varscan2
- DHX15 | c.594A>C p.A198= | Silent (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- DIP2A | c.4224G>T p.A1408= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs112595846; called by muse, mutect2, varscan2
- DSP | c.3906C>T p.R1302= | Silent (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- FAM47B | c.1081C>A p.R361= | Silent (SNP) | VAF 81/131 reads (62%) | catalogued as COSV61454876; called by muse, mutect2, varscan2
- FBXO2 | c.163C>T p.L55= | Silent (SNP) | VAF 63/226 reads (28%) | catalogued as rs1253170309; called by muse, mutect2, varscan2
- GFRA2 | c.951C>T p.I317= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as rs576343653; called by muse, mutect2, varscan2
- GUF1 | c.795G>A p.Q265= | Silent (SNP) | VAF 17/271 reads (6%) | called by muse, mutect2
- HDC | c.657C>A p.L219= | Silent (SNP) | VAF 84/341 reads (25%) | catalogued as COSV51068677; called by muse, mutect2, varscan2
- HORMAD1 | c.1074G>T p.R358= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs1055998757, COSV55046194; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1368T>A p.T456= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs1057515851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL2RA | c.732C>A p.A244= | Silent (SNP) | VAF 117/296 reads (40%) | called by muse, mutect2, varscan2
- INSYN2B | c.240G>A p.S80= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1033924671, COSV56991757; called by muse, mutect2, varscan2
- IRX6 | c.438C>A p.G146= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV51861552; called by muse, mutect2, varscan2
- IZUMO1 | c.540G>A p.L180= | Silent (SNP) | VAF 50/230 reads (22%) | called by muse, mutect2, varscan2
- KIDINS220 | c.3966G>T p.T1322= | Silent (SNP) | VAF 62/215 reads (29%) | catalogued as rs371285385; called by muse, mutect2, varscan2
- LAD1 | c.583C>T p.L195= | Silent (SNP) | VAF 35/312 reads (11%) | called by muse, mutect2, varscan2
- LOXHD1 | c.4203G>T p.P1401= | Silent (SNP) | VAF 45/126 reads (36%) | called by muse, mutect2, varscan2
- MARK1 | c.1773T>A p.A591= | Silent (SNP) | VAF 45/389 reads (12%) | called by muse, mutect2, varscan2
- MCHR2 | c.855T>C p.Y285= | Silent (SNP) | VAF 59/449 reads (13%) | catalogued as rs374378949; called by muse, mutect2, varscan2
- NHSL1 | c.2937G>T p.P979= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- NYNRIN | c.2910T>C p.S970= | Silent (SNP) | VAF 217/320 reads (68%) | called by muse, mutect2, varscan2
- PCDHB16 | c.909G>A p.L303= | Silent (SNP) | VAF 64/242 reads (26%) | called by muse, mutect2, varscan2
- PLCL1 | c.2022G>T p.P674= | Silent (SNP) | VAF 85/249 reads (34%) | catalogued as rs558973603, COSV70822050; called by muse, mutect2, varscan2
- POTED | c.1518G>A p.Q506= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- PRDM9 | c.1698C>T p.H566= | Silent (SNP) | VAF 165/554 reads (30%) | catalogued as rs776606930; called by muse, mutect2, varscan2
- PRDM9 | c.2484G>A p.G828= | Silent (SNP) | VAF 28/596 reads (5%) | catalogued as rs1164234725, COSV57003347; called by muse, mutect2
- PRRC2B | c.57G>A p.S19= | Silent (SNP) | VAF 37/227 reads (16%) | catalogued as rs761892321; called by muse, mutect2, varscan2
- PSG6 | c.387G>T p.G129= | Silent (SNP) | VAF 61/193 reads (32%) | catalogued as COSV51834512; called by muse, mutect2, varscan2
- PYGL | c.2532C>A p.V844= | Silent (SNP) | VAF 23/204 reads (11%) | called by muse, mutect2, varscan2
- PYGO2 | c.894G>T p.R298= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs1299627342; called by muse, mutect2
- SLC4A8 | c.27G>T p.P9= | Silent (SNP) | VAF 47/133 reads (35%) | called by muse, mutect2, varscan2
- SLC8A2 | c.660C>T p.S220= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV52639862; called by muse, mutect2, varscan2
- SOGA1 | c.3936C>T p.R1312= | Silent (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- SP4 | c.1872C>A p.A624= | Silent (SNP) | VAF 56/210 reads (27%) | called by muse, mutect2, varscan2
- TEX45 | c.393C>T p.A131= | Silent (SNP) | VAF 81/168 reads (48%) | catalogued as rs1406842509; called by muse, mutect2, varscan2
- TNRC6C | c.657G>T p.P219= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV56945137; called by muse, mutect2, varscan2
- TRAF7 | c.1638C>T p.I546= | Silent (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- TRPC5 | c.513C>A p.P171= | Silent (SNP) | VAF 85/157 reads (54%) | catalogued as COSV99459934; called by muse, mutect2, varscan2
- TUBA3C | c.441T>A p.S147= | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- USP17L7 | c.876C>G p.A292= | Silent (SNP) | VAF 236/538 reads (44%) | called by muse, mutect2
- VSIG8 | c.840C>A p.A280= | Silent (SNP) | VAF 80/330 reads (24%) | called by muse, mutect2, varscan2
- WDR48 | c.378C>G p.A126= | Silent (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- ZNF213 | c.1095C>T p.G365= | Silent (SNP) | VAF 20/360 reads (6%) | catalogued as rs762436045; called by muse, mutect2
- ABI3BP | c.1786+577T>C | Intron (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- AC022415.2 | c.*2384G>A | 3'UTR (SNP) | VAF 86/222 reads (39%) | called by muse, mutect2, varscan2
- AC024598.1 | c.1130-1506A>G | Intron (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- AC024598.1 | c.1130-1504G>T | Intron (SNP) | VAF 20/258 reads (8%) | catalogued as COSV60823735; called by muse, mutect2
- AK2 | c.*2958C>T | 3'UTR (SNP) | VAF 25/345 reads (7%) | called by muse, mutect2
- AKAP8 | c.-12C>A | 5'UTR (SNP) | VAF 59/165 reads (36%) | called by muse, mutect2, varscan2
- ALMS1 | c.11547+32G>A | Intron (SNP) | VAF 66/444 reads (15%) | called by muse, mutect2, varscan2
- CPSF6 | c.270+753G>T | Intron (SNP) | VAF 25/156 reads (16%) | called by muse, varscan2
- DIP2A | c.3969+13_3969+14insT | Intron (INS) | VAF 60/248 reads (24%) | called by mutect2, pindel*, varscan2*
- GBA3 | c.59-8376del | Intron (DEL) | VAF 138/436 reads (32%) | called by mutect2, pindel, varscan2
- GNAO1 | c.723+6991C>A | Intron (SNP) | VAF 55/297 reads (19%) | catalogued as COSV52618968; called by muse, mutect2
- HBE1 | c.-267+102639G>T | Intron (SNP) | VAF 50/276 reads (18%) | called by muse, mutect2, varscan2
- LYPLA2P2 | n.425G>A | RNA (SNP) | VAF 24/242 reads (10%) | catalogued as rs1421062194; called by muse, mutect2
- NPR3 | chr5:32710721 A>G | 5'Flank (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2204C>T | Intron (SNP) | VAF 16/250 reads (6%) | catalogued as rs1490804758; called by muse, mutect2
- ODF2L | c.811-10T>G | Intron (SNP) | VAF 19/139 reads (14%) | called by muse, varscan2
- PIGK | c.987-7119G>T | Intron (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- PROS1 | c.*35G>T | 3'UTR (SNP) | VAF 30/113 reads (27%) | catalogued as COSV101260524; called by muse, mutect2, varscan2
- RAD21 | chr8:116874970 C>T | 5'Flank (SNP) | VAF 15/201 reads (7%) | called by muse, mutect2
- RASSF10 | c.-212C>T | 5'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+5218G>A | Intron (SNP) | VAF 20/144 reads (14%) | catalogued as rs888994945; called by muse, mutect2, varscan2
- RN7SL214P | chr15:77919294 G>A | 5'Flank (SNP) | VAF 60/270 reads (22%) | catalogued as rs961446140; called by muse, mutect2, varscan2
- SC5D | c.210+71T>C | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- SERPINB13 | c.473-322A>T | Intron (SNP) | VAF 47/162 reads (29%) | called by muse, mutect2, varscan2
- SH2D6 | n.329+16del | Intron (DEL) | VAF 36/230 reads (16%) | called by mutect2, pindel, varscan2
- SLC6A4 | c.-99G>T | 5'UTR (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99911421; called by muse, varscan2
- SSPOP | n.1389G>A | RNA (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- TAF6L | c.436+12T>C | Intron (SNP) | VAF 9/173 reads (5%) | catalogued as rs1404390865, COSV99585279; called by muse, mutect2
- TEX36-AS1 | n.514+414G>T | Intron (SNP) | VAF 84/177 reads (47%) | called by muse, mutect2, varscan2
- TNS2 | c.3575-29G>T | Intron (SNP) | VAF 79/423 reads (19%) | called by muse, mutect2, varscan2
- TP53TG3D | c.*205G>T | 3'UTR (SNP) | VAF 115/437 reads (26%) | called by muse, mutect2, varscan2
- TSC22D1 | c.2912+33254C>T | Intron (SNP) | VAF 67/245 reads (27%) | called by muse, mutect2, varscan2
- TTLL9 | c.*3C>T | 3'UTR (SNP) | VAF 51/197 reads (26%) | called by muse, mutect2, varscan2
- YBX1 | c.167-212C>A | Intron (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2
- ZNF567 | c.10-138A>G | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as rs776107127; called by mutect2, varscan2
